Somatic mutation profile of tumor specimen 0DHE05 from CCDI case PBBUFI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.3 years (1,555 days).
Specimen 0DHE05: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e036553c-c9d8-4c74-9c8c-db61d45baa8a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DHDZB (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/db9f3e01-35e2-4e33-a17e-64ff7efa17f8

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CSMD1 | c.2254G>A p.V752M (on ENST00000520002; = p.V751M on NM_033225.6) | Missense Mutation (SNP) | VAF 176/637 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs369449812; called by muse, mutect2, varscan2
- PGBD2 | c.723G>C p.R241S | Missense Mutation (SNP) | VAF 88/884 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.6); called by muse, mutect2
